Somatic mutation profile of tumor specimen TCGA-E7-A7DU-01A (aliquot TCGA-E7-A7DU-01A-11D-A32B-08) from TCGA case TCGA-E7-A7DU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: Low Grade; Age at diagnosis: 73.9 years (27,000 days).
Specimen TCGA-E7-A7DU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eb23ba9-1da6-44d2-bbb9-4f062fe4c079.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A7DU-10A (Blood Derived Normal), aliquot TCGA-E7-A7DU-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d829afeb-40fe-45e0-8392-97e0716ebb6d

The open-access MAF lists 294 somatic variants for this specimen: 213 protein-altering or splice-affecting, 71 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 71, Nonsense Mutation 17, Intron 7, Splice Site 4, 3'UTR 2, Nonstop Mutation 1, Translation Start Site 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*164G>T | 3'UTR (SNP) | VAF 133/233 reads (57%) | catalogued as rs121913479, CM960656, COSV53390089, COSV99600444; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.385-2A>T p.X129_splice | Splice Site (SNP) | VAF 15/21 reads (71%) | hotspot (GDC flag); catalogued as COSV65037583, COSV65048184; called by mutect2, varscan2
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV62788964; called by muse, mutect2, varscan2
- ABL2 | c.476G>A p.S159N (on ENST00000502732 / NM_007314.4; = p.S144N on NM_005158.5) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61011515; called by muse, mutect2, varscan2
- ACADS | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs766747544, COSV54368189; called by muse, mutect2, varscan2
- ADAMTS10 | c.2358G>C p.Q786H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54352513; called by muse, mutect2, varscan2
- ADCY8 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 141/203 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201905912, COSV53898118; called by muse, mutect2, varscan2
- ADGRA3 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV99293177; called by muse, mutect2, varscan2
- AGA | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV52805811; called by muse, mutect2, varscan2
- AHNAK2 | c.11570C>T p.S3857F | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV60909095, COSV60928979; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- ANKIB1 | c.3208G>C p.D1070H | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV99728849; called by muse, mutect2, varscan2
- ANKS1A | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64459109, COSV64462764; called by muse, mutect2, varscan2
- APOBEC2 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV55142165; called by muse, mutect2, varscan2
- ARHGAP35 | c.3871G>C p.E1291Q | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV68329474; called by muse, mutect2, varscan2
- ARHGEF18 | c.1180G>C p.D394H (on ENST00000359920 / NM_001130955.2; = p.D290H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV104409390, COSV60467369; called by muse, mutect2, varscan2
- ARID1A | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 92/448 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV61372729, COSV61385466; called by muse, varscan2
- ASXL2 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV55454493; called by muse, mutect2
- ASXL3 | c.5124G>A p.M1708I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV52458941; called by muse, mutect2, varscan2
- ATP8B1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1296397254, COSV52173361; called by muse, mutect2, varscan2
- ATR | c.5263C>A p.Q1755K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.53); catalogued as COSV63384509, COSV63393892; called by muse, mutect2, varscan2
- BABAM2 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 46/141 reads (33%) | catalogued as COSV100567684, COSV59632850; called by muse, mutect2, varscan2
- BICD2 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 66/154 reads (43%) | catalogued as COSV100794072; called by muse, varscan2
- BIRC6 | c.5473G>C p.E1825Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70196159; called by muse, varscan2
- BRAP | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs989023764, COSV59535691; called by muse, mutect2, varscan2
- BSN | c.2082G>C p.Q694H | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV56513784; called by muse, mutect2, varscan2
- C15orf39 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100641290; called by muse, mutect2, varscan2
- C2CD2 | c.1059G>C p.K353N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100298111; called by muse, mutect2
- CA12 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV51604360; called by muse, mutect2, varscan2
- CC2D2A | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs765073945, COSV67502457; called by muse, mutect2, varscan2
- CCDC88A | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55057330; called by muse, mutect2, varscan2
- CCDC92 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1191133385, COSV53018757; called by muse, mutect2, varscan2
- CCDC93 | c.1871C>G p.S624C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV60119854; called by muse, mutect2, varscan2
- CCT6B | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV58488039; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDKN2AIP | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56626815; called by muse, mutect2, varscan2
- CELF2 | c.558G>C p.Q186H (on ENST00000416382 / NM_001025077.3; = p.Q193H on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59969017, COSV59970162; called by muse, mutect2, varscan2
- CEP131 | c.1980G>C p.Q660H (on ENST00000269392 / NM_001319228.2; = p.Q657H on NM_014984.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs760427864, COSV53954320; called by muse, mutect2
- CEP83 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV60406852; called by muse, mutect2, varscan2
- CFAP53 | c.927G>T p.L309F | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68351415; called by muse, mutect2, varscan2
- CLASP2 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56277053, COSV56282419, COSV56293642; called by muse, mutect2, varscan2
- CMTR1 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs372628932; called by muse, mutect2, varscan2
- COL4A1 | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370670458; called by muse, mutect2, varscan2
- COL6A6 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100650160, COSV62031441; called by muse, mutect2, varscan2
- CYP4F2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.336); catalogued as COSV55616655; called by muse, varscan2
- DBT | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV64495000, COSV64496117; called by muse, mutect2, varscan2
- DCST2 | c.1224G>T p.E408D | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV55050347; called by muse, mutect2, varscan2
- DCTN2 | c.601G>A p.D201N (on ENST00000548249 / NM_001261413.2; = p.D206N on NM_006400.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV63073275; called by muse, mutect2, varscan2
- DENND4B | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV100768582; called by muse, mutect2
- DHX40 | c.1468C>G p.P490A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1301657350, COSV99232883; called by mutect2, varscan2
- DLG5 | c.4580C>T p.A1527V | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV64946990; called by muse, mutect2, varscan2
- DNAH3 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV54506828; called by muse, mutect2, varscan2
- DNAJB12 | c.1109-1G>C p.X370_splice (on ENST00000338820; = p.X336_splice on NM_017626.6 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 29/68 reads (43%) | catalogued as COSV58759785; called by muse, mutect2, varscan2
- DOCK7 | c.2450C>G p.S817C | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.827); catalogued as COSV51997397, COSV52013178; called by muse, mutect2, varscan2
- DOP1B | c.6251C>G p.S2084C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67692315; called by muse, mutect2, varscan2
- DSC3 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64571625; called by muse, mutect2, varscan2
- DYRK2 | c.1549G>C p.E517Q (on ENST00000344096 / NM_006482.3; = p.E444Q on NM_003583.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV59845508; called by muse, mutect2, varscan2
- ECHDC1 | c.581G>A p.G194D (on ENST00000531967 / NM_001139510.1; = p.G188D on NM_001002030.2) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58931535; called by muse, mutect2, varscan2
- EIF2A | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56405162; called by muse, mutect2, varscan2
- EIF4G3 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV51675477; called by muse, mutect2, varscan2
- ELMO2 | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs768485829, COSV51681589; called by muse, mutect2, varscan2
- EMC3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55277516; called by muse, mutect2
- EPHA6 | c.2387G>A p.R796K (on ENST00000389672 / NM_001080448.3; = p.R188K on NM_173655.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV101064895, COSV67559861; called by muse, mutect2, varscan2
- EPN1 | c.1546G>A p.V516I (on ENST00000270460 / NM_001321263.1; = p.V490I on NM_013333.3) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs374261347; called by muse, mutect2, varscan2
- ERCC4 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61310904, COSV61314369; called by muse, mutect2, varscan2
- ERMP1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs151153615; called by muse, mutect2, varscan2
- ERP44 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV52430060; called by muse, mutect2, varscan2
- ESR2 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50828887, COSV50839210; called by muse, mutect2, varscan2
- FASTKD2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs768207380, COSV52697534; called by muse, mutect2, varscan2
- FCHO2 | c.2432G>C p.*811Sext*27 | Nonstop Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100530535; called by muse, mutect2, varscan2
- FCRL3 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV63839841; called by muse, mutect2, varscan2
- FIS1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV56190952; called by muse, mutect2, varscan2
- GAL3ST4 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV52784049; called by muse, mutect2, varscan2
- GCLC | c.1825C>A p.Q609K (on ENST00000643939; = p.Q607K on NM_001498.4) | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV57593860; called by muse, mutect2, varscan2
- GFPT1 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV61946787; called by muse, mutect2, varscan2
- GORASP1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV56530564; called by muse, mutect2, varscan2
- GPR31 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV64761184; called by muse, mutect2, varscan2
- GRIA4 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as COSV56884407; called by muse, mutect2, varscan2
- GRIK1 | c.2381C>G p.T794S | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.373); catalogued as COSV58711999; called by muse, mutect2, varscan2
- GRIK1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as COSV100516510; called by muse, mutect2
- H3-3B | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV54665608; called by muse, mutect2, varscan2
- HCN1 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100299760; called by muse, mutect2, varscan2
- HIVEP1 | c.5222C>T p.S1741L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65099208; called by muse, mutect2, varscan2
- HOXA6 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV56071920; called by muse, mutect2, varscan2
- HOXC10 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57725846; called by muse, mutect2, varscan2
- HTR1D | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV58447347; called by muse, mutect2, varscan2
- IGDCC4 | c.2536+1G>A p.X846_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as rs918996775, COSV61535645; called by muse, mutect2, varscan2
- IL36B | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV52084682; called by muse, mutect2, varscan2
- ING5 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57978106; called by muse, mutect2, varscan2
- INPP4B | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV53713020; called by muse, mutect2, varscan2
- IPO7 | c.2487G>A p.L829= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as COSV65684332; called by muse, mutect2, varscan2
- ITGA1 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV50876803, COSV50876825; called by muse, mutect2, varscan2
- ITGAL | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV63320430; called by muse, mutect2, varscan2
- JCAD | c.3987G>C p.E1329D | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV64757895; called by muse, mutect2, varscan2
- KCTD6 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); catalogued as COSV61873340; called by muse, mutect2, varscan2
- KHDRBS2 | c.394C>G p.H132D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55430938; called by muse, mutect2, varscan2
- KIAA0232 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV100300785, COSV56923550; called by muse, mutect2, varscan2
- KIF4B | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV70528133; called by muse, mutect2, varscan2
- KIF4B | c.3543G>C p.K1181N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.051); catalogued as COSV70528139, COSV70531711; called by muse, mutect2, varscan2
- LCP1 | c.1118G>C p.R373T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.134); catalogued as COSV59939736, COSV59941728; called by muse, mutect2, varscan2
- LONRF2 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV66539599; called by muse, mutect2, varscan2
- LRFN3 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.069); catalogued as rs368851132; called by muse, mutect2, varscan2
- LRP2 | c.8952G>C p.E2984D | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55543356, COSV55559747; called by muse, varscan2
- LRRC2 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV56125163; called by muse, mutect2, varscan2
- MBIP | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs770324179, COSV59253312; called by muse, mutect2, varscan2
- MBTPS1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58569768; called by muse, mutect2, varscan2
- MEST | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV56227621; called by muse, mutect2, varscan2
- MKS1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV58302801; called by muse, mutect2, varscan2
- MLXIP | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs767309891, COSV100038652; called by muse, mutect2, varscan2
- MTARC2 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV100830897; called by muse, mutect2, varscan2
- MTHFD1L | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100944776, COSV66224013; called by muse, mutect2, varscan2
- MTMR11 | c.416G>A p.R139Q (on ENST00000439741 / NM_001145862.2; = p.R67Q on NM_181873.3) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs370127696; called by muse, mutect2, varscan2
- MUC3A | c.8276C>T p.S2759F | Missense Mutation (SNP) | VAF 44/526 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV60211471; called by muse, mutect2
- MYH10 | c.3619G>C p.E1207Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV52595897; called by muse, mutect2, varscan2
- MYO1A | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV55652174; called by muse, varscan2
- NEPRO | c.1302C>G p.I434M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV55605949; called by muse, mutect2, varscan2
- NEU3 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53635790; called by muse, mutect2, varscan2
- NF1 | c.6307C>T p.L2103F (on ENST00000358273 / NM_001042492.3; = p.L2082F on NM_000267.3) | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1555534719, COSV62194795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NINL | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53999151; called by muse, mutect2, varscan2
- NLRC4 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1283568725, COSV61590938, COSV61595153; ClinVar: uncertain significance; called by muse, mutect2
- NUCB1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.978); catalogued as COSV54385289; called by muse, mutect2, varscan2
- NUP155 | c.681C>A p.F227L (on ENST00000231498 / NM_153485.3; = p.F168L on NM_004298.4) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51527468; called by muse, mutect2, varscan2
- NUP210L | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as rs528494343, COSV55142669; called by muse, mutect2, varscan2
- ODF1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV53431764; called by muse, mutect2, varscan2
- OR2A12 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs752194572, COSV68821085; called by muse, mutect2, varscan2
- OR2J3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.894); catalogued as rs750082580, COSV65848706; called by muse, mutect2, varscan2
- OR4K2 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs1475038321, COSV53848403; called by muse, mutect2, varscan2
- P4HA1 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as COSV54959093; called by muse, mutect2, varscan2
- PATJ | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV57156637; called by muse, mutect2, varscan2
- PCDHA12 | c.1868A>G p.H623R | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782755927, COSV56481489; called by muse, mutect2, varscan2
- PCDHB2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99523052; called by muse, mutect2, varscan2
- PCDHGA7 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs182497799, COSV53892197; called by muse, mutect2, varscan2
- PDE1A | c.106A>T p.R36* | Nonsense Mutation (SNP) | VAF 29/50 reads (58%) | catalogued as COSV100113870, COSV59517997; called by muse, mutect2, varscan2
- PDE1C | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs772676533, COSV58504873; called by muse, mutect2, varscan2
- PDZRN4 | c.2410G>A p.A804T (on ENST00000402685 / NM_001164595.2; = p.A546T on NM_013377.4) | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs375067300; called by muse, mutect2, varscan2
- PHF6 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV59699959; called by muse, mutect2, varscan2
- PIGS | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52023803; called by muse, mutect2, varscan2
- PIP4P2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs1338877144, COSV53437689; called by muse, mutect2, varscan2
- PKN2 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs776454578, COSV65142099; called by muse, mutect2, varscan2
- PLBD2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757529097, COSV55105659; called by muse, varscan2
- PLXNA3 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV63753342; called by muse, mutect2, varscan2
- PPP1R18 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as COSV51294747; called by muse, mutect2, varscan2
- PTCHD4 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | catalogued as rs910334387, COSV59777413; called by muse, mutect2, varscan2
- PTGFR | c.838C>G p.L280V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV66114489; called by muse, mutect2, varscan2
- PUS7 | c.297G>C p.E99D | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV62676017; called by muse, mutect2, varscan2
- RAB12 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.103); catalogued as COSV61398125; called by muse, mutect2, varscan2
- RASAL2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62710526; called by muse, mutect2, varscan2
- RBM15 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs375984907; called by muse, mutect2, varscan2
- RITA1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55320499; called by muse, mutect2, varscan2
- RPL26L1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV54199229; called by muse, mutect2, varscan2
- RRP15 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV65117394; called by muse, mutect2, varscan2
- RYR2 | c.13015C>T p.Q4339* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as COSV100769524; called by muse, mutect2, varscan2
- RYR3 | c.3771G>A p.M1257I | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs774954880, COSV66779974; called by muse, mutect2, varscan2
- SAGE1 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.443); catalogued as COSV61011873; called by muse, mutect2, varscan2
- SETD7 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1267650451, COSV56799455; called by muse, mutect2, varscan2
- SH3RF2 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV63037508, COSV63040715; called by muse, mutect2, varscan2
- SLC25A39 | c.574C>T p.Q192* (on ENST00000377095 / NM_001143780.3; = p.Q184* on NM_016016.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs1380502185, COSV99835194; called by muse, mutect2, varscan2
- SLF1 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54367915, COSV54373593; called by muse, mutect2, varscan2
- SMG1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV67169721; called by muse, mutect2, varscan2
- SMS | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65113687; called by muse, mutect2, varscan2
- SOX5 | c.2246A>T p.D749V | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV58620476; called by muse, mutect2, varscan2
- SP140 | c.1488G>C p.K496N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59446902; called by muse, mutect2, varscan2
- SPEN | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1201312983, COSV65358486; called by muse, mutect2, varscan2
- SPHKAP | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV60867453; called by muse, mutect2, varscan2
- SPRED2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62691410; called by muse, mutect2, varscan2
- STAG2 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV54352046, COSV54355890; called by muse, mutect2, varscan2
- STAG2 | c.2887C>T p.Q963* | Nonsense Mutation (SNP) | VAF 66/74 reads (89%) | catalogued as COSV54360925; called by muse, mutect2, varscan2
- STAT2 | c.472-1G>A p.X158_splice | Splice Site (SNP) | VAF 42/153 reads (27%) | catalogued as COSV58474466; called by muse, mutect2, varscan2
- SULT1B1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779362138, COSV60206651; called by muse, mutect2, varscan2
- SYNE1 | c.13285G>A p.D4429N (on ENST00000367255 / NM_182961.4; = p.D4358N on NM_033071.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.283); catalogued as rs762245840, COSV54920584; called by muse, mutect2, varscan2
- TASOR2 | c.4651C>G p.P1551A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV60165868; called by muse, mutect2, varscan2
- TBC1D17 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV55577081, COSV55577401; called by muse, mutect2, varscan2
- TBC1D17 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as COSV55577412; called by muse, mutect2, varscan2
- TENM1 | c.5458C>T p.R1820* | Nonsense Mutation (SNP) | VAF 36/61 reads (59%) | catalogued as COSV100949746; called by muse, mutect2, varscan2
- TENM4 | c.5329G>C p.E1777Q | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV53611937, COSV53630350; called by muse, mutect2, varscan2
- THRSP | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs145822616; called by muse, mutect2, varscan2
- TLR6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV67935024; called by muse, mutect2, varscan2
- TMCO4 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 20/33 reads (61%) | catalogued as COSV53872305, COSV99615488, COSV99616333; called by muse, varscan2
- TP53 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as CM044948, COSV52679410, COSV52730707, COSV52765316; called by muse, varscan2
- TPR | c.6358G>A p.G2120S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs1385077720, COSV66599726, COSV66599818; called by muse, mutect2, varscan2
- TRPM7 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.215); catalogued as COSV57913935; called by muse, mutect2, varscan2
- TRRAP | c.5356G>A p.E1786K (on ENST00000359863 / NM_001244580.1; = p.E1768K on NM_003496.3) | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV62840253; called by muse, mutect2, varscan2
- TRUB2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as COSV65759344; called by muse, mutect2, varscan2
- TSFM | c.654G>A p.M218I (on ENST00000323833 / NM_001172696.2; = p.M197I on NM_005726.6) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57680665; called by muse, mutect2, varscan2
- TSPOAP1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1339630790, COSV52105104; called by muse, mutect2
- TTC30A | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV63100523; called by muse, mutect2, varscan2
- TTF2 | c.2788C>G p.L930V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65632130; called by muse, mutect2, varscan2
- TXLNA | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV101009835, COSV65314721; called by muse, mutect2, varscan2
- UNC13D | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV52883255; called by muse, mutect2, varscan2
- UNC5A | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52837435; called by muse, mutect2, varscan2
- USF3 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.197); catalogued as COSV57076278; called by muse, mutect2
- USP15 | c.1987G>A p.D663N (on ENST00000280377 / NM_001351159.2; = p.D634N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.537); catalogued as COSV54788627; called by muse, mutect2, varscan2
- USP4 | c.2047G>C p.D683H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV55535218; called by muse, mutect2, varscan2
- UTY | c.1250C>A p.S417* | Nonsense Mutation (SNP) | VAF 16/18 reads (89%) | catalogued as COSV100229521, COSV58870857; called by muse, varscan2
- WDR11 | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.658); catalogued as COSV54785933, COSV54787985; called by muse, mutect2, varscan2
- WDR17 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV54569316; called by muse, mutect2, varscan2
- WDR6 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.976); catalogued as rs771254196, COSV58244102; called by muse, mutect2, varscan2
- WDR88 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100866506; called by muse, mutect2
- WIPF3 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs1328415375, COSV54210211; called by muse, mutect2
- WNK1 | c.1758G>C p.E586D | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV60026874; called by muse, mutect2, varscan2
- XIRP2 | c.574G>C p.E192Q (on ENST00000628543; = p.E367Q on NM_152381.6) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.114); catalogued as COSV54685681; called by muse, mutect2, varscan2
- XKRX | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60707492; called by muse, mutect2, varscan2
- ZBED2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV51913339, COSV99342587; called by muse, mutect2, varscan2
- ZBTB18 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV62396379; called by muse, mutect2, varscan2
- ZFP2 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV63724794; called by muse, mutect2, varscan2
- ZFX | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58446703; called by muse, mutect2, varscan2
- ZNF217 | c.3058C>T p.Q1020* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as COSV100184314, COSV100184381; called by muse, mutect2, varscan2
- ZNF468 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV54693519; called by muse, mutect2, varscan2
- ZNF616 | c.2297G>C p.R766T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV57509717; called by muse, mutect2, varscan2
- ZSWIM5 | c.3124G>T p.V1042L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.918); catalogued as COSV55799102; called by muse, mutect2, varscan2
- EQTN | c.320_321dup p.S108Nfs*32 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- PPP6R3 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2
- TRGC2 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- AACS | c.183C>T p.F61= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV55534913; called by muse, mutect2, varscan2
- ABCA8 | c.4095C>G p.L1365= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs1041332554, COSV52195683, COSV52209073; called by muse, mutect2
- AEBP1 | c.2196C>T p.R732= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV56255780; called by muse, mutect2, varscan2
- ANKRD28 | c.2940G>A p.L980= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV67517076, COSV67519655; called by muse, mutect2, varscan2
- ARHGEF16 | c.1509G>A p.L503= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1458538812, COSV65681446; called by muse, mutect2, varscan2
- ATXN10 | c.1392G>A p.L464= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV53293996; called by muse, mutect2, varscan2
- B3GAT1 | c.39C>T p.I13= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs185221306, COSV56995382; called by muse, mutect2, varscan2
- BCL11B | c.2631C>T p.H877= (on ENST00000357195 / NM_001282237.2; = p.H806= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs990764552, COSV61733830; called by muse, mutect2, varscan2
- CAST | c.975A>G p.L325= (on ENST00000341926; = p.L408= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV57782713; called by muse, mutect2, varscan2
- COLEC11 | c.477G>A p.E159= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV52591852; called by muse, mutect2, varscan2
- COPA | c.3414C>A p.A1138= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV54098640; called by muse, mutect2, varscan2
- CP | c.987G>A p.Q329= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs150470431, COSV52829319; called by muse, mutect2, varscan2
- CPNE1 | c.348G>T p.L116= (on ENST00000352393; = p.L121= on NM_003915.5) | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100467338; called by muse, mutect2, varscan2
- CSE1L | c.1587C>G p.L529= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs771282629, COSV53700539; called by muse, mutect2, varscan2
- DECR1 | c.57C>T p.L19= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV55166738; called by muse, mutect2, varscan2
- DNAJC13 | c.6411C>G p.L2137= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV53446568; called by muse, mutect2, varscan2
- DPH7 | c.1212G>A p.R404= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs1457437624, COSV53021481; called by muse, mutect2, varscan2
- EFR3A | c.2259G>A p.E753= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV54453245; called by muse, mutect2, varscan2
- ELP3 | c.78G>C p.L26= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV56457933; called by muse, mutect2, varscan2
- ENTPD1 | c.1270C>T p.L424= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV64600300; called by muse, mutect2, varscan2
- EYS | c.423G>A p.L141= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs764381172, CD102738, COSV60978003; called by muse, mutect2, varscan2
- FAM135B | c.4057C>T p.L1353= | Silent (SNP) | VAF 129/254 reads (51%) | catalogued as rs764408584, COSV52708835; called by muse, mutect2, varscan2
- GPC6 | c.1227C>T p.D409= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs776525061, COSV65500404, COSV65507180; called by muse, mutect2, varscan2
- GPR162 | c.1347C>T p.L449= (on ENST00000311268 / NM_019858.2; = p.L165= on NM_014449.2) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs782562218, COSV51831338; called by muse, mutect2, varscan2
- GRID2 | c.189C>T p.I63= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV56178306, COSV56232400; called by muse, mutect2, varscan2
- GRWD1 | c.513G>A p.E171= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99474334; called by muse, mutect2
- HSD3B1 | c.264C>G p.V88= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV52489687; called by muse, mutect2, varscan2
- LGI1 | c.648G>C p.S216= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV65057531; called by muse, mutect2, varscan2
- LHFPL5 | c.111C>T p.S37= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs757495483, COSV64177237; called by muse, mutect2, varscan2
- LRRN1 | c.444C>G p.L148= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV60012654; called by muse, mutect2, varscan2
- MAP3K4 | c.3180G>A p.Q1060= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as COSV62330524; called by muse, mutect2, varscan2
- MDN1 | c.528C>G p.L176= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV65518055; called by muse, mutect2, varscan2
- MKI67 | c.54C>T p.P18= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV64072869; called by muse, mutect2, varscan2
- MNDA | c.351C>T p.T117= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs375325126; called by muse, varscan2
- NAALAD2 | c.1056C>T p.I352= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV58959140; called by muse, mutect2, varscan2
- NLRC5 | c.3705C>T p.L1235= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV52650145; called by muse, mutect2, varscan2
- OCA2 | c.2484C>G p.L828= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV62339867; called by muse, mutect2, varscan2
- OPN5 | c.486C>T p.F162= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55244429; called by muse, mutect2, varscan2
- OR10H5 | c.846C>T p.L282= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV58277536; called by muse, mutect2, varscan2
- OR2T2 | c.870C>T p.I290= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100737639; called by muse, mutect2, varscan2
- PLEKHA5 | c.2976C>T p.F992= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV54694989; called by muse, mutect2, varscan2
- PPP2R1A | c.894G>T p.V298= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV59042387, COSV59042773; called by muse, mutect2, varscan2
- PPP2R3A | c.2505G>C p.L835= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV53860266; called by muse, mutect2, varscan2
- PRPF8 | c.2556G>T p.V852= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV59261157; called by muse, mutect2, varscan2
- PSMB3 | c.48G>A p.G16= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs768202940; called by muse, mutect2, varscan2
- PSMC6 | c.42C>A p.I14= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV71628577; called by mutect2, varscan2
- PTP4A2 | c.471C>T p.F157= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as COSV59773399; called by muse, mutect2, varscan2
- PURA | c.510C>T p.I170= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58761895; called by muse, mutect2, varscan2
- RAB3A | c.662G>A p.*221= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV55853372, COSV99717962; called by muse, mutect2, varscan2
- RAN | c.399G>A p.A133= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs769792621, COSV54562173; called by muse, mutect2, varscan2
- RBP3 | c.105C>T p.L35= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- ROGDI | c.603C>A p.L201= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV59021000; called by muse, mutect2, varscan2
- RPS6KB2 | c.432C>G p.L144= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV57047985; called by muse, mutect2, varscan2
- RRH | c.748C>T p.L250= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV58490750; called by muse, varscan2
- RRP1B | c.1308G>T p.L436= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV61478520; called by muse, mutect2, varscan2
- SEMG1 | c.1236T>C p.N412= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV54871972; called by muse, mutect2, varscan2
- SGSM2 | c.414G>A p.E138= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV52156145; called by muse, mutect2, varscan2
- SMAD7 | c.1233C>T p.F411= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV50988840; called by muse, mutect2, varscan2
- SOAT1 | c.1131C>G p.L377= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV62652905; called by muse, mutect2, varscan2
- SOWAHB | c.153C>T p.F51= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV57554115; called by muse, mutect2, varscan2
- SYNE1 | c.9519C>A p.I3173= (on ENST00000367255 / NM_182961.4; = p.I3180= on NM_033071.3) | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV54920628; called by muse, mutect2, varscan2
- TAOK1 | c.54C>T p.L18= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1279401192, COSV55588806, COSV55590579; called by muse, mutect2, varscan2
- TBCD | c.1449G>A p.L483= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV62798123; called by mutect2, varscan2
- TECTA | c.4683G>A p.T1561= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs149232569, COSV50690200; called by muse, mutect2, varscan2
- TMEM147 | c.243G>C p.L81= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV52866063, COSV52870579, COSV99382657; called by muse, mutect2, varscan2
- UNC13A | c.1810C>T p.L604= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1042558830, COSV99407901; called by muse, mutect2, varscan2
- VIPAS39 | c.1200G>A p.K400= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV58938659, COSV58939514; called by muse, mutect2, varscan2
- WDR1 | c.246G>A p.L82= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99306064; called by muse, mutect2
- ZNF277 | c.1032G>A p.V344= | Silent (SNP) | VAF 110/156 reads (71%) | catalogued as COSV62463376; called by muse, mutect2, varscan2
- ZNF33B | c.598C>T p.L200= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs773120205, COSV63941953; called by muse, mutect2, varscan2
- ZNF775 | c.432C>T p.F144= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61613151; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622818 G>T | 3'Flank (SNP) | VAF 6/43 reads (14%) | catalogued as rs868113665, COSV100247059; called by muse, mutect2, varscan2
- CNOT1 | c.3523-846G>A | Intron (SNP) | VAF 20/102 reads (20%) | catalogued as COSV99799912; called by muse, mutect2, varscan2
- IKBIP | c.297+8250G>A | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as rs139350531; called by muse, mutect2
- IKBIP | c.297+8127G>C | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as COSV54488702; called by muse, mutect2, varscan2
- IKBIP | c.297+8031G>A | Intron (SNP) | VAF 20/108 reads (19%) | catalogued as rs1328624583, COSV54488714; called by muse, mutect2, varscan2
- IKBIP | c.297+7873G>C | Intron (SNP) | VAF 17/84 reads (20%) | catalogued as COSV54488728; called by muse, mutect2, varscan2
- IKBIP | c.297+7730G>A | Intron (SNP) | VAF 20/87 reads (23%) | catalogued as COSV54488741; called by muse, mutect2, varscan2
- PDGFB | c.63+3037C>T | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as COSV58646016; called by muse, mutect2, varscan2
- TNFRSF18 | c.*236G>C | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100148857, COSV100148867; called by muse, mutect2
